Somatic mutation profile of tumor specimen TCGA-CC-A3MA-01A (aliquot TCGA-CC-A3MA-01A-11D-A20W-10) from TCGA case TCGA-CC-A3MA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.3 years (22,375 days).
Specimen TCGA-CC-A3MA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61c6b025-4742-4c28-b7d3-5f64436e5781.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A3MA-10A (Blood Derived Normal), aliquot TCGA-CC-A3MA-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6649ce78-b82e-4f11-b3c3-7c91e04e109e

The open-access MAF lists 45 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 28, Silent 11, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 75/123 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567555667, COSV52680942, COSV52985275; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BAHCC1 | c.3618T>A p.H1206Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV57022828; called by muse, mutect2, varscan2
- CAPN10 | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.232); catalogued as COSV54374779, COSV54376566; called by muse, mutect2, varscan2
- CARD10 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52654391; called by muse, mutect2, varscan2
- CNTNAP3 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 224/920 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1348353139, COSV99904119; called by muse, mutect2
- COL4A4 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.336); catalogued as rs199562472, COSV61629546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMBX1 | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs1300510056, COSV63601653; called by muse, mutect2, varscan2
- EFEMP1 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV62614980; called by muse, mutect2, varscan2
- FAM83C | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); catalogued as rs138265873; called by muse, mutect2, varscan2
- GHDC | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56986602; called by muse, mutect2, varscan2
- GPRASP1 | c.857G>T p.R286M | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV64354785; called by muse, mutect2, varscan2
- HACE1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as COSV53499201; called by muse, mutect2, varscan2
- HSPA13 | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as rs200321727, COSV53464550; called by muse, mutect2, varscan2
- KAT6B | c.5665A>G p.M1889V | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs781631671, COSV54742088; called by muse, mutect2, varscan2
- KLHL3 | c.1591+1G>T p.X531_splice | Splice Site (SNP) | VAF 38/87 reads (44%) | catalogued as COSV59050907; called by muse, mutect2, varscan2
- MATN2 | c.518C>G p.P173R | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54706789; called by muse, mutect2, varscan2
- MUC16 | c.37423C>T p.R12475W | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.656); catalogued as rs566860711, COSV67444861; called by muse, mutect2, varscan2
- OLFML2B | c.272G>T p.R91M | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV54193875, COSV54195481; called by muse, mutect2, varscan2
- PIK3C2B | c.4101C>G p.I1367M | Missense Mutation (SNP) | VAF 73/325 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV65809013; called by muse, mutect2, varscan2
- PLEKHA4 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1045015565, COSV54361040; called by muse, mutect2, varscan2
- RNF157 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs144334591; called by muse, mutect2, varscan2
- SLITRK2 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV100157654, COSV59422638, COSV59427826; called by muse, mutect2, varscan2
- TAS1R2 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 84/126 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV64743590; called by muse, mutect2, varscan2
- TRIM16L | c.966G>T p.K322N | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV67459072; called by muse, mutect2, varscan2
- WDHD1 | c.3356A>G p.Q1119R | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as COSV62212848; called by muse, mutect2, varscan2
- WSB1 | c.474T>A p.Y158* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV52214522; called by muse, mutect2, varscan2
- ZAN | c.326T>A p.L109Q | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61805003; called by muse, mutect2, varscan2
- ZNF567 | c.1464G>T p.M488I (on ENST00000536254 / NM_001322913.1; = p.M457I on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV62444221; called by muse, mutect2, varscan2
- ZNF576 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60670177; called by muse, mutect2, varscan2
- ZNF630 | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52094967; called by muse, mutect2, varscan2
- ANKRD11 | c.7708_7713del p.S2570_Q2571del | In Frame Del (DEL) | VAF 27/76 reads (36%) | called by mutect2, pindel, varscan2
- ARID2 | c.4460_4472del p.P1487Qfs*25 | Frame Shift Del (DEL) | VAF 40/89 reads (45%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.6426_6427insTT p.E2143Lfs*5 | Frame Shift Ins (INS) | VAF 48/202 reads (24%) | called by mutect2, pindel, varscan2
- RASA1 | c.1639_1651del p.H547Nfs*19 | Frame Shift Del (DEL) | VAF 50/176 reads (28%) | called by mutect2, pindel, varscan2
- ASB13 | c.417C>T p.V139= | Silent (SNP) | VAF 59/99 reads (60%) | catalogued as rs748891348, COSV63089909; called by muse, mutect2, varscan2
- BCL2 | c.600A>G p.E200= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV61373066; called by muse, mutect2, varscan2
- BRSK1 | c.1830C>T p.L610= | Silent (SNP) | VAF 57/172 reads (33%) | catalogued as COSV58664589; called by muse, mutect2, varscan2
- DSP | c.3675C>G p.S1225= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV65791112; called by muse, mutect2, varscan2
- F10 | c.894C>T p.G298= | Silent (SNP) | VAF 26/410 reads (6%) | catalogued as rs778741024, COSV65020771; called by muse, mutect2
- FARP1 | c.744A>T p.G248= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV60330106; called by muse, mutect2
- LRP1B | c.12210A>G p.L4070= | Silent (SNP) | VAF 85/228 reads (37%) | catalogued as COSV67186615; called by muse, mutect2, varscan2
- PNPLA2 | c.582T>C p.C194= | Silent (SNP) | VAF 48/76 reads (63%) | catalogued as COSV100351929; called by muse, varscan2
- SLC24A3 | c.1752C>T p.S584= | Silent (SNP) | VAF 93/216 reads (43%) | catalogued as rs753628756, COSV60111643; called by muse, mutect2, varscan2
- TENM2 | c.8121C>G p.A2707= (on ENST00000518659 / NM_001122679.2; = p.A2468= on NM_001080428.3) | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV69122664; called by muse, mutect2, varscan2
- ZNF777 | c.1371C>T p.D457= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as rs1446231880, COSV56096174; called by muse, mutect2, varscan2
